CCDI case PBCBYG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/74d07f46-4c08-4c34-bb8d-df56637f61a9

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Angiomatoid fibrous histiocytoma: ICD-O-3 morphology code: 8836/1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 7.8 years (2,834 days).

Biospecimens (3 samples)
- Sample 0DOBSP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOBT3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOBTB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
